Somatic mutation profile of tumor specimen C3L-00358-01 (aliquot CPT0002210008) from CPTAC case C3L-00358, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen C3L-00358-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9fbc967-2ef5-42e3-9ade-fda75cf2f560.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00358-31 (Blood Derived Normal), aliquot CPT0004360002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f352171-ce05-4c59-a62b-429ee4b025f9

The open-access MAF lists 144 somatic variants for this specimen: 100 protein-altering or splice-affecting, 22 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 22, Intron 10, Nonsense Mutation 5, Frame Shift Del 5, In Frame Del 4, 5'UTR 4, 3'UTR 3, Splice Region 2, RNA 2, 5'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.490A>G p.K164E | Missense Mutation (SNP) | VAF 124/185 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs879254249, COSV52676020, COSV52700231, COSV52728094, COSV52766542; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARMH3 | c.326G>C p.R109P | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.73); catalogued as COSV100228878; called by muse, mutect2
- ASPA | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs778121276; called by muse, mutect2, varscan2
- BICRA | c.3859G>A p.G1287S | Missense Mutation (SNP) | VAF 184/277 reads (66%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.563); catalogued as rs1402566668; called by muse, mutect2, varscan2
- BRINP3 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66514914, COSV66524518; called by muse, mutect2
- C4orf54 | c.1605C>A p.N535K | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1387407932; called by muse, mutect2, varscan2
- CCNE1 | c.916C>G p.H306D | Missense Mutation (SNP) | VAF 111/652 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52903713, COSV52905047; called by muse, mutect2, varscan2
- CELSR2 | c.2782G>A p.V928M | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.821); catalogued as rs1447823734; called by muse, mutect2, varscan2
- CFHR2 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 15/187 reads (8%) | catalogued as COSV66381066; called by muse, mutect2
- EPPK1 | c.4471C>T p.R1491W | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs782125308; called by muse, mutect2, varscan2
- EPS8 | c.600G>A p.R200= | Splice Region (SNP) | VAF 28/156 reads (18%) | catalogued as COSV55528701; called by muse, mutect2, varscan2
- FDPS | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 88/259 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs753523692, COSV100756157; called by muse, mutect2, varscan2
- H4C2 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV55137306; called by muse, mutect2, varscan2
- HARS1 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1295541335, COSV56909238; ClinVar: uncertain significance; called by muse, mutect2
- HELZ2 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs757788400; called by muse, mutect2, varscan2
- HOXD12 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV66832726, COSV66832882; called by muse, mutect2, varscan2
- IFIT1 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.156); catalogued as rs149964072; called by muse, mutect2, varscan2
- IGHG4 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 53/278 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as rs374177525; called by muse, mutect2
- IGSF9B | c.541G>A p.G181S | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.035); catalogued as rs761894478; called by muse, mutect2, varscan2
- IL18R1 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs749556086, COSV52126166; called by muse, mutect2, varscan2
- KRT79 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 8/253 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.741); catalogued as COSV57942168; called by muse, mutect2
- KSR2 | c.2269G>A p.V757I | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.203); catalogued as rs371702381; called by muse, mutect2, varscan2
- NAA25 | c.2174A>G p.D725G | Missense Mutation (SNP) | VAF 57/230 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as rs1486757342; called by muse, mutect2, varscan2
- NDC1 | c.1606C>T p.R536W | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868754994, COSV99323619; called by muse, mutect2
- OR2T35 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV100442155; called by mutect2, varscan2
- OR51G2 | c.481A>G p.I161V | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.994); catalogued as COSV58992777; called by muse, mutect2, varscan2
- PADI1 | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 135/242 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1309094619; called by muse, mutect2, varscan2
- PARVB | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as rs377537511; called by muse, mutect2, varscan2
- PTCH2 | c.3269C>G p.A1090G | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.581); catalogued as COSV63400187; called by muse, mutect2, varscan2
- RAPGEF3 | c.686C>T p.T229M (on ENST00000389212; = p.T187M on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs755563251; called by muse, mutect2, varscan2
- RGMB | c.760G>A p.D254N (on ENST00000513185 / NM_001366508.1; = p.D295N on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/172 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs752647942; called by muse, mutect2, varscan2
- SALL2 | c.653G>A p.G218D | Missense Mutation (SNP) | VAF 78/165 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs780448573; called by muse, mutect2, varscan2
- SALL3 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs1051188427; called by mutect2, varscan2
- SH3RF2 | c.1730C>A p.T577K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as rs543563186; called by muse, mutect2
- SIX3 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV53228498; called by muse, mutect2
- SLC18B1 | c.574T>G p.F192V | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.636); catalogued as rs773720026; called by muse, varscan2
- SLC26A11 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.045); catalogued as rs775782388, COSV63279821; called by muse, mutect2, varscan2
- SNF8 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 31/72 reads (43%) | catalogued as rs779528259; called by muse, mutect2, varscan2
- SNX29 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372445217; called by muse, mutect2, varscan2
- SPEN | c.4624C>T p.R1542* | Nonsense Mutation (SNP) | VAF 9/156 reads (6%) | catalogued as COSV65360482; called by muse, mutect2
- SSTR4 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as rs750847560, COSV54799603; called by muse, mutect2, varscan2
- SYT17 | c.1402C>G p.P468A | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV62546260; called by muse, mutect2
- TC2N | c.1171G>A p.V391M | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146216998; called by muse, mutect2, varscan2
- TMEM200A | c.1393A>G p.R465G | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs200539088; called by muse, mutect2, varscan2
- TMEM80 | c.374G>A p.W125* (on ENST00000526170 / NM_001276274.1; = p.W187* on NM_174940.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/166 reads (7%) | catalogued as COSV100585839; called by muse, mutect2
- TRPC7 | c.2459G>A p.R820H | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as rs1347360317; called by muse, mutect2, varscan2
- AIFM2 | c.497C>A p.P166H | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.562); called by muse, mutect2
- ANKRD18B | c.711_715del p.D238Cfs*5 | Frame Shift Del (DEL) | VAF 15/75 reads (20%) | called by mutect2, pindel, varscan2
- ANTXRL | c.1126_1128del p.R376del | In Frame Del (DEL) | VAF 30/212 reads (14%) | called by mutect2, pindel, varscan2
- C2orf73 | c.432T>G p.N144K | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.01); called by muse, mutect2
- CACHD1 | c.986A>G p.N329S | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CACNA1F | c.566A>C p.D189A | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CCNE1 | c.997C>G p.P333A | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD40LG | c.472G>T p.G158W | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CD96 | c.30_36del p.Y11Sfs*31 | Frame Shift Del (DEL) | VAF 54/258 reads (21%) | called by mutect2, pindel, varscan2
- CDKAL1 | c.643C>G p.L215V | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CFAP99 | c.1099_1117del p.V367Sfs*19 | Frame Shift Del (DEL) | VAF 41/181 reads (23%) | called by mutect2, pindel, varscan2
- CKMT2 | c.1010G>C p.S337T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- CRNKL1 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 26/293 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.688); called by muse, mutect2
- CSMD1 | c.9087_9101del p.A3030_T3034del (on ENST00000520002; = p.A3029_T3033del on NM_033225.6) | In Frame Del (DEL) | VAF 8/61 reads (13%) | called by mutect2, pindel
- CSMD2 | c.9722_9730del p.K3241_P3243del | In Frame Del (DEL) | VAF 14/119 reads (12%) | called by mutect2, pindel
- DESI2 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 118/313 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMGDH | c.1372C>T p.P458S | Missense Mutation (SNP) | VAF 49/287 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- DMXL1 | c.3428A>G p.D1143G | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, varscan2
- DMXL1 | c.3533A>C p.K1178T | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, varscan2
- DNAH11 | c.8197G>C p.D2733H | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPYS | c.578C>G p.A193G | Missense Mutation (SNP) | VAF 30/321 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DSEL | c.1831T>C p.F611L | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM160B2 | c.1284C>A p.D428E | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- FOXA2 | c.1038_1057del p.A347Pfs*8 (on ENST00000377115 / NM_153675.3; = p.A353Pfs*8 on NM_021784.5) | Frame Shift Del (DEL) | VAF 50/230 reads (22%) | called by mutect2, pindel
- FSTL5 | c.247G>C p.G83R | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, mutect2
- GRM7 | c.1767dup p.W590Lfs*28 | Frame Shift Ins (INS) | VAF 28/86 reads (33%) | called by mutect2, pindel, varscan2
- INTS2 | c.830T>G p.L277R | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCNJ4 | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- L2HGDH | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- LGSN | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.009); called by muse, mutect2
- LRIG1 | c.1366A>C p.I456L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEH1 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 51/273 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- MCC | c.1768C>G p.L590V | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- MCM3AP | c.4914T>G p.F1638L | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- NKAP | c.644G>C p.S215T | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- NKX1-1 | c.465C>T p.N155= | Splice Region (SNP) | VAF 24/117 reads (21%) | called by muse, mutect2, varscan2
- OR5C1 | c.824_832del p.D275_M277del | In Frame Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- OR5D18 | c.694G>T p.V232F | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2
- PCDHB6 | c.2017G>C p.E673Q | Missense Mutation (SNP) | VAF 47/322 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- PRKDC | c.12331G>C p.A4111P | Missense Mutation (SNP) | VAF 82/179 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB3GAP2 | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 60/340 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RCOR2 | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SBNO2 | c.2937G>T p.K979N | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.832); called by muse, mutect2
- SETD1B | c.5460C>A p.N1820K | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC27A3 | c.1642C>T p.Q548* (on ENST00000271857; = p.Q420* on NM_024330.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 71/186 reads (38%) | called by muse, mutect2, varscan2
- SYNE1 | c.3133G>C p.E1045Q (on ENST00000367255 / NM_182961.4; = p.E1052Q on NM_033071.3) | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- TLN1 | c.5489C>G p.S1830C | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); called by muse, mutect2
- TRMT12 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 41/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPV2 | c.204_213del p.P69Tfs*27 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | called by mutect2, pindel
- TYW1 | c.1087G>T p.A363S | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF239 | c.202G>C p.V68L | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZNF530 | c.1136A>G p.Y379C | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF675 | c.1235C>G p.T412S | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- ZNF763 | c.986G>A p.R329K (on ENST00000358987 / NM_001367172.2; = p.R332K on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- A4GNT | c.210C>T p.S70= | Silent (SNP) | VAF 55/130 reads (42%) | catalogued as rs374392631, COSV52629894; called by muse, mutect2, varscan2
- ASL | c.1170C>T p.A390= | Silent (SNP) | VAF 67/374 reads (18%) | called by muse, mutect2, varscan2
- ATXN7L1 | c.36G>C p.S12= | Silent (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- BHLHA15 | c.192C>T p.S64= | Silent (SNP) | VAF 21/268 reads (8%) | catalogued as rs765278821; called by muse, mutect2
- DCC | c.1107T>C p.D369= | Silent (SNP) | VAF 44/172 reads (26%) | catalogued as rs775175456; called by muse, mutect2, varscan2
- DLG2 | c.90G>A p.L30= | Silent (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2, varscan2
- FAT4 | c.9472C>T p.L3158= | Silent (SNP) | VAF 27/90 reads (30%) | called by muse, mutect2, varscan2
- GPR158 | c.1296C>T p.F432= | Silent (SNP) | VAF 21/175 reads (12%) | catalogued as rs1219324824, COSV66264911; called by muse, mutect2, varscan2
- MEOX2 | c.372G>A p.P124= | Silent (SNP) | VAF 62/202 reads (31%) | catalogued as COSV56291543; called by muse, mutect2, varscan2
- MRPL13 | c.60C>G p.L20= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as COSV59962611; called by muse, mutect2, varscan2
- OCA2 | c.750C>T p.I250= | Silent (SNP) | VAF 94/354 reads (27%) | catalogued as rs377144100; called by muse, mutect2, varscan2
- OR10J5 | c.573C>T p.T191= | Silent (SNP) | VAF 11/154 reads (7%) | called by muse, mutect2
- OR6V1 | c.447T>G p.A149= | Silent (SNP) | VAF 118/229 reads (52%) | called by muse, mutect2, varscan2
- P2RY10 | c.411G>A p.K137= | Silent (SNP) | VAF 46/172 reads (27%) | catalogued as rs374748915; called by muse, varscan2
- PASD1 | c.2268G>A p.A756= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as rs372806683, COSV64855942; called by muse, mutect2, varscan2
- PRAMEF27 | c.411G>A p.V137= | Silent (SNP) | VAF 16/35 reads (46%) | called by mutect2, varscan2
- REXO4 | c.978C>T p.H326= | Silent (SNP) | VAF 47/220 reads (21%) | catalogued as rs782490309, COSV100905733; called by muse, mutect2, varscan2
- RHBDF2 | c.2457C>T p.L819= | Silent (SNP) | VAF 16/162 reads (10%) | catalogued as rs563507854; called by muse, mutect2, varscan2
- SH3RF2 | c.1731G>C p.T577= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs748868731; called by muse, mutect2
- ZMYND15 | c.1260C>G p.P420= | Silent (SNP) | VAF 12/160 reads (8%) | catalogued as rs1254692106, COSV52640578; called by muse, mutect2
- ZNF516 | c.1572C>T p.F524= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as rs1426177849; called by muse, mutect2, varscan2
- ZSWIM6 | c.3339G>C p.L1113= | Silent (SNP) | VAF 21/181 reads (12%) | called by muse, mutect2, varscan2
- AC011294.1 | n.312del | RNA (DEL) | VAF 16/76 reads (21%) | called by mutect2, pindel, varscan2
- ADGRE3 | c.393+31C>A | Intron (SNP) | VAF 9/111 reads (8%) | called by muse, mutect2
- ANAPC11 | c.110-487C>T | Intron (SNP) | VAF 38/132 reads (29%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499010 C>T | 5'Flank (SNP) | VAF 31/122 reads (25%) | catalogued as rs376520805; called by muse, mutect2, varscan2
- CBL | c.-45G>T | 5'UTR (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- CHRNB1 | c.243+26A>G | Intron (SNP) | VAF 98/146 reads (67%) | called by muse, mutect2, varscan2
- COX6B1 | c.-11-16C>T | Intron (SNP) | VAF 199/450 reads (44%) | catalogued as rs903173519; called by muse, mutect2, varscan2
- CRIPT | c.-55T>G | 5'UTR (SNP) | VAF 83/180 reads (46%) | catalogued as COSV99482616; called by muse, varscan2
- DBF4B | c.1189+369C>T | Intron (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
- F11R | c.*6G>T | 3'UTR (SNP) | VAF 78/191 reads (41%) | called by muse, mutect2, varscan2
- HGF | c.482+1116G>C | Intron (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- HSF1 | c.1142+392G>A | Intron (SNP) | VAF 11/218 reads (5%) | catalogued as rs868914001; called by muse, mutect2
- KCTD1 | c.-15-47232_-15-47218del | Intron (DEL) | VAF 10/49 reads (20%) | called by pindel, varscan2
- KLRC3 | c.*61G>A | 3'UTR (SNP) | VAF 37/185 reads (20%) | catalogued as rs1041571876; called by muse, mutect2, varscan2
- KMT5B | c.1174+1033G>A | Intron (SNP) | VAF 48/125 reads (38%) | called by muse, mutect2, varscan2
- KRT15 | c.582-50C>G | Intron (SNP) | VAF 14/381 reads (4%) | called by muse, mutect2
- NBR2 | n.416G>T | RNA (SNP) | VAF 106/426 reads (25%) | called by muse, mutect2, varscan2
- NDUFA11 | chr19:5893193 C>G | 3'Flank (SNP) | VAF 11/195 reads (6%) | catalogued as COSV99398919; called by muse, mutect2
- NPEPL1 | chr20:58691493 G>A | 5'Flank (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- WT1 | c.-25G>A | 5'UTR (SNP) | VAF 23/97 reads (24%) | called by muse, mutect2, varscan2
- XIAP | c.*5592C>G | 3'UTR (SNP) | VAF 38/104 reads (37%) | called by muse, mutect2, varscan2
- ZEB2 | c.-112T>A | 5'UTR (SNP) | VAF 21/111 reads (19%) | called by muse, mutect2, varscan2
